Somatic mutation profile of tumor specimen TARGET-20-PATDNN-09A (aliquot TARGET-20-PATDNN-09A-01D) from TARGET case TARGET-20-PATDNN, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,262 days).
Specimen TARGET-20-PATDNN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4456940-01cc-4093-ab9f-43cc9ff76921.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATDNN-10A (Blood Derived Normal), aliquot TARGET-20-PATDNN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b59163c-8987-4642-a0de-065565602af5

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 88/219 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SETD2 | c.7436C>T p.S2479F | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57438622; called by muse, mutect2
- SETD2 | c.5696_5697insC p.E1899Dfs*12 | Frame Shift Ins (INS) | VAF 129/380 reads (34%) | catalogued as COSV57449093; called by mutect2, pindel, varscan2
